Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A2EK, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A2EK-01A (Primary Tumor).

PATHOLOGY REPORT

1CD-0-3

carcinoma, urothelial, NOS 8/20/3
Site: bladder, NOS C67.9 hu
5/31/11

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH GRADE (GRADE 3), INVASIVE INTO MUSCULARIS PROPRIA.

UROTHELIAL CARCINOMA INVOLVING PROSTATIC DUCTS AND ACINI.

No invasion into prostatic stroma is identified.

No lymphovascular invasion is identified.

Entire report and diagnosis completed by

MD

GROSS DESCRIPTION

(A) BLADDER TUMOR – Received are multiple fragments of tan-pink to gray-white soft, rubbery, partly cauterized, friable soft tissue (3.0 x 2.5 x 1.0 cm). Specimen is submitted entirely in A1-A3.

CLINICAL HISTORY

Bladder cancer.

Source: NCI Genomic Data Commons file 8ac0e21d-25a8-47db-9e1c-d3a2d77cea52 (TCGA-G2-A2EK.935F1F7B-F048-4B44-81F0-1E56842A73B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).